CCDI case PBCLSI — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/47b7dd86-0316-48ff-aa88-60b1fc21a841

Demographics
Sex at birth: female; Race: white.

Diagnoses (1)
1. Medulloblastoma, NOS: ICD-O-3 morphology code: 9470/3; Tissue or organ of origin: Brain stem; Age at diagnosis: 2.2 years (791 days).

Biospecimens (3 samples)
- Sample 0DUVT3: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DUVTC: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DUVTQ: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
